Somatic mutation profile of tumor specimen 0DW72X from CCDI case PBCMDX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.5 years (549 days).
Specimen 0DW72X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 016de94e-80b9-4844-bed4-eac55ce817dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW72J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a402a669-d74f-427d-a4f6-9dd742e7a715

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JPH2 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 132/338 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as rs530754608, COSV100652585; called by muse, varscan2
- HOOK1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 282/752 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); called by muse, varscan2
- LRCH2 | c.1181A>T p.K394M | Missense Mutation (SNP) | VAF 180/642 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, varscan2
- NR2C1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 79/203 reads (39%) | called by muse, varscan2
- SNORC | c.74-87C>A | Intron (SNP) | VAF 4/25 reads (16%) | called by muse, varscan2
